Gene-level copy-number profile of tumor specimen TCGA-EB-A6L9-06A from TCGA case TCGA-EB-A6L9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.2 years (20,537 days).
Specimen TCGA-EB-A6L9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.53e8eaee-46ba-4671-b898-6d4a86b35b35.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A6L9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b96d498-1cd6-4091-a315-797acb157db4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,387; copy number 2: 56,563; copy number 3: 760; copy number 4: 76; copy number 5: 15; copy number 6: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A6L9-06A-11D-A32M-01): tumor purity 0.12, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:45,164,816–46,394,228, 15 genes, copy number 5: LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820.
- chr3:145,523,538–146,606,216, 18 genes, copy number 6: LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:146,921,795–146,927,429, 1 gene, copy number 6: LINC02010.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
